Somatic mutation profile of cancer-model specimen HCM-CSHL-0082-C25-85A (3D Organoid; aliquot HCM-CSHL-0082-C25-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0082-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.7 years (28,367 days).
Specimen HCM-CSHL-0082-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77c090e8-9c7a-4aba-a8d8-7d47d25b2e50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0082-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0082-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76b8f417-87f7-491c-9a8f-ada35e42e11d

The open-access MAF lists 65 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 19, Intron 4, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 106/225 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CNTN4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 133/242 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018920181, COSV61867465; called by muse, mutect2, varscan2
- IL17RD | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs776344177, COSV56335407, COSV56343092; called by muse, mutect2, varscan2
- ITGAD | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 110/210 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs754577254, COSV101210442; called by muse, mutect2, varscan2
- ITIH6 | c.3416G>A p.R1139H | Missense Mutation (SNP) | VAF 119/120 reads (99%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs1308877323; called by muse, mutect2, varscan2
- KLF5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 114/214 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66614378, COSV66615313; called by muse, mutect2, varscan2
- KMT2C | c.1796A>T p.D599V | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51422339; called by muse, mutect2, varscan2
- NEUROD4 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 112/211 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754528345, COSV99669698; called by muse, mutect2, varscan2
- NPHP4 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs201713171; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OPLAH | c.2671G>A p.V891I | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs782815785, COSV70678656; called by muse, mutect2, varscan2
- PKHD1 | c.6629G>C p.G2210A | Missense Mutation (SNP) | VAF 169/354 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM100425, COSV61898375; called by muse, mutect2, varscan2
- PLP2 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 160/160 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV66239409; called by muse, mutect2, varscan2
- SAMHD1 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 105/198 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53432753; called by muse, mutect2, varscan2
- SPP1 | c.637G>A p.A213T (on ENST00000395080 / NM_001040058.2; = p.A199T on NM_000582.2) | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs746808333, COSV99421049; called by muse, mutect2, varscan2
- THADA | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs372826539; called by muse, mutect2, varscan2
- ZNF398 | c.1565G>A p.R522H (on ENST00000475153 / NM_170686.3; = p.R351H on NM_020781.4) | Missense Mutation (SNP) | VAF 161/294 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1013965037; called by muse, mutect2, varscan2
- ZNF623 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 91/347 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs765195158, COSV71697086; called by muse, mutect2, varscan2
- ZSCAN22 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1265345677; called by muse, mutect2, varscan2
- ADGRG4 | c.4872G>T p.M1624I | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD6 | c.2051A>T p.E684V (on ENST00000339746 / NM_001242809.2; = p.E679V on NM_014942.4) | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- APCDD1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 190/392 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATAD2B | c.923G>T p.R308M | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V0A4 | c.429T>G p.N143K | Missense Mutation (SNP) | VAF 181/296 reads (61%) | SIFT tolerated (0.45); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AUTS2 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 70/117 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DEPDC1 | c.2202dup p.V735Sfs*17 (on ENST00000456315 / NM_001114120.3; = p.V451Sfs*17 on NM_017779.6) | Frame Shift Ins (INS) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- DUOX1 | c.3760C>G p.L1254V | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2
- FLYWCH1 | c.470G>A p.G157D (on ENST00000253928 / NM_001308068.2; = p.G156D on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/324 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LINGO4 | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 117/221 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MTMR10 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NEK4 | c.2083T>A p.Y695N | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- NKAIN3 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUTM1 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OXSM | c.590A>T p.K197I | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- PPFIA4 | c.1637C>T p.A546V (on ENST00000447715; = p.G535= on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/446 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SASH1 | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- SLCO1B3 | c.1912G>A p.V638I | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBXA2R | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 249/268 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFBR1 | c.1106dup p.N370Kfs*13 | Frame Shift Ins (INS) | VAF 75/105 reads (71%) | called by mutect2, pindel, varscan2
- TRIM46 | c.1399C>G p.R467G | Missense Mutation (SNP) | VAF 150/354 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TSBP1 | c.1255C>A p.Q419K (on ENST00000617061; = p.Q424K on NM_006781.5) | Missense Mutation (SNP) | VAF 125/220 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF570 | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 91/122 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKR7A2 | c.480C>T p.H160= | Silent (SNP) | VAF 249/557 reads (45%) | called by muse, mutect2, varscan2
- ATP2B2 | c.495C>T p.V165= | Silent (SNP) | VAF 205/430 reads (48%) | called by muse, mutect2, varscan2
- C12orf42 | c.687C>T p.P229= | Silent (SNP) | VAF 129/246 reads (52%) | catalogued as rs1403964707; called by muse, mutect2, varscan2
- CCBE1 | c.138C>A p.I46= | Silent (SNP) | VAF 54/269 reads (20%) | catalogued as COSV101480461; called by muse, mutect2, varscan2
- CERS1 | c.369C>A p.T123= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- CSMD2 | c.6165C>T p.T2055= | Silent (SNP) | VAF 125/455 reads (27%) | catalogued as rs1342501922, COSV99595682; called by muse, mutect2, varscan2
- DRD2 | c.924C>T p.P308= | Silent (SNP) | VAF 138/282 reads (49%) | catalogued as rs146497846; called by muse, mutect2, varscan2
- FOXI2 | c.858C>G p.T286= | Silent (SNP) | VAF 101/221 reads (46%) | called by muse, mutect2, varscan2
- IMPACT | c.516G>A p.P172= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs752510391, COSV52421629; called by muse, mutect2, varscan2
- MGAT5B | c.2205C>T p.T735= (on ENST00000569840 / NM_001199172.2; = p.T733= on NM_144677.3) | Silent (SNP) | VAF 147/307 reads (48%) | catalogued as rs373336679; called by muse, mutect2, varscan2
- MUC5B | c.15849C>A p.T5283= | Silent (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- NPFFR1 | c.828G>A p.A276= | Silent (SNP) | VAF 157/379 reads (41%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.2419C>T p.L807= (on ENST00000400915 / NM_001042663.3; = p.L770= on NM_020631.6) | Silent (SNP) | VAF 188/377 reads (50%) | called by muse, mutect2, varscan2
- POLD1 | c.741C>T p.N247= | Silent (SNP) | VAF 102/129 reads (79%) | catalogued as rs758321599; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAD51D | c.726C>G p.G242= | Silent (SNP) | VAF 94/560 reads (17%) | called by muse, mutect2, varscan2
- SLC17A9 | c.12C>T p.P4= | Silent (SNP) | VAF 143/250 reads (57%) | called by muse, mutect2, varscan2
- TTLL11 | c.1458G>T p.T486= | Silent (SNP) | VAF 95/97 reads (98%) | catalogued as rs199532582, COSV58652912; called by muse, mutect2, varscan2
- WNT10A | c.742C>A p.R248= | Silent (SNP) | VAF 137/308 reads (44%) | catalogued as CM111791, COSV104384135; called by muse, mutect2, varscan2
- ZNF648 | c.348C>T p.S116= | Silent (SNP) | VAF 258/518 reads (50%) | called by muse, mutect2
- ARHGEF4 | chr2:130915890 G>A | 5'Flank (SNP) | VAF 45/100 reads (45%) | catalogued as rs1291315147; called by muse, mutect2, varscan2
- DYNC1H1 | c.7614+37G>A | Intron (SNP) | VAF 226/500 reads (45%) | catalogued as rs760515260; called by muse, mutect2, varscan2
- EYS | c.1767-7876T>G | Intron (SNP) | VAF 138/312 reads (44%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-1253C>T | Intron (SNP) | VAF 72/144 reads (50%) | catalogued as COSV55168078; called by muse, mutect2, varscan2
- MTA1 | c.1813+25C>T | Intron (SNP) | VAF 108/227 reads (48%) | catalogued as rs782795181; called by muse, mutect2, varscan2
